Somatic mutation profile of tumor specimen MP2PRT-PAVFRZ-TMP1-A (aliquot MP2PRT-PAVFRZ-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVFRZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,172 days).
Specimen MP2PRT-PAVFRZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14303b46-3509-4c4b-a2d0-14ccade04f85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFRZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFRZ-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9309122-f5da-4498-bb45-d987d358d6f4

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 26/313 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 83/415 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- C5orf47 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 341/818 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV60864823; called by muse, mutect2, varscan2
- MEIS2 | c.496G>A p.E166K (on ENST00000561208 / NM_170675.5; = p.E153K on NM_002399.3) | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54932630; called by muse, mutect2, varscan2
- NLRC4 | c.1357C>T p.R453* | Nonsense Mutation (SNP) | VAF 145/366 reads (40%) | catalogued as rs765641913, COSV61591640; ClinVar: likely benign; called by muse, mutect2, varscan2
- SETD2 | c.6910A>G p.T2304A | Missense Mutation (SNP) | VAF 145/284 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1559672400; called by muse, mutect2, varscan2
- SPEG | c.4822G>A p.G1608S | Missense Mutation (SNP) | VAF 39/401 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs1289884424; called by muse, mutect2, varscan2
- CHPF | c.426del p.H143Tfs*9 | Frame Shift Del (DEL) | VAF 389/1017 reads (38%) | called by mutect2, pindel, varscan2
- COL9A1 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 143/353 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- EIF2S3B | c.719T>A p.V240E | Missense Mutation (SNP) | VAF 141/286 reads (49%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ETV4 | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 144/361 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- HKDC1 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 191/435 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MGA | c.1065-1dup p.X355_splice | Splice Site (INS) | VAF 77/84 reads (92%) | called by mutect2, pindel*, varscan2*
- SLC16A12 | c.560C>A p.T187N | Missense Mutation (SNP) | VAF 194/416 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- TTN | c.15109G>A p.D5037N (on ENST00000591111; = p.D4110N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/269 reads (40%) | PolyPhen benign (0.229); called by muse, mutect2, varscan2
- KCNG4 | c.1401G>A p.E467= | Silent (SNP) | VAF 18/630 reads (3%) | called by muse, mutect2
- PKD2L1 | c.1344C>T p.F448= | Silent (SNP) | VAF 27/263 reads (10%) | catalogued as rs779603220; called by muse, mutect2, varscan2
- SZT2 | c.1194C>T p.D398= | Silent (SNP) | VAF 52/548 reads (9%) | called by muse, mutect2
- VANGL2 | c.771C>T p.A257= | Silent (SNP) | VAF 153/375 reads (41%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1046+2947G>A | Intron (SNP) | VAF 147/344 reads (43%) | catalogued as rs747921046, COSV58442745; called by muse, mutect2, varscan2
